CPTAC case SC-0492 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9254b3b4-358f-4517-a132-71f5f7587d03

Demographics
Sex at birth: male; Vital status: Alive.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin of lower limb and hip; Age at diagnosis: 65.0 years (23,741 days); AJCC staging edition: 8th; AJCC pathologic T: T4a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Progression or recurrence: yes; Days to recurrence: 426 days (1.2 years); Days to last follow up: 1,552 days (4.2 years); Clark level: IV.
   Pathology details: Breslow thickness: 13.

Biospecimens (1 sample)
- Sample S-1911-008772: Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Frozen; Initial weight: 170 mg; Method of sample procurement: Tumor Resection.
